Somatic mutation profile of tumor specimen TCGA-BR-8690-01A (aliquot TCGA-BR-8690-01A-11D-2394-08) from TCGA case TCGA-BR-8690, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 54.4 years (19,855 days).
Specimen TCGA-BR-8690-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e20effa-4af8-4108-be9a-8edfb49115db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8690-10A (Blood Derived Normal), aliquot TCGA-BR-8690-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dc25475-2930-42ec-8497-45e4370366e3

The open-access MAF lists 167 somatic variants for this specimen: 124 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 40, Nonsense Mutation 9, Splice Site 4, Frame Shift Ins 3, Frame Shift Del 2, 5'UTR 2, Nonstop Mutation 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137852384, CM910117, COSV64274739; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV55116669; called by muse, mutect2
- AASS | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.909); catalogued as COSV62791033, COSV62791204; called by muse, mutect2
- ABCB1 | c.1224+2T>C p.X408_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as COSV55957991; called by muse, mutect2, varscan2
- ABCB8 | c.1051C>T p.Q351* (on ENST00000297504 / NM_001282291.2; = p.Q334* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV52507961; called by muse, mutect2
- ABCC9 | c.3145C>A p.L1049I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as COSV53979985; called by muse, mutect2, varscan2
- ACTG2 | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV61829182; called by muse, mutect2, varscan2
- ACTN2 | c.1951C>G p.P651A | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs1416165135, COSV63977089; called by muse, mutect2, varscan2
- ACTN4 | c.2405A>C p.E802A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53148547; called by muse, mutect2
- ADAM17 | c.2474A>T p.*825Lext*7 | Nonstop Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV60400802; called by muse, mutect2
- ADAM33 | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62934166; called by muse, mutect2, varscan2
- ADGRL4 | c.1119G>C p.W373C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876351, COSV66063786, COSV66064462; called by muse, mutect2, varscan2
- ANO6 | c.1773A>C p.R591S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57664849; called by muse, mutect2, varscan2
- ARHGAP24 | c.482A>T p.D161V (on ENST00000395184 / NM_001025616.3; = p.D68V on NM_031305.3) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51991901; called by muse, mutect2, varscan2
- ARHGAP24 | c.585G>T p.K195N (on ENST00000395184 / NM_001025616.3; = p.K102N on NM_031305.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51991920; called by muse, mutect2, varscan2
- ARHGAP24 | c.2104C>T p.R702* (on ENST00000395184 / NM_001025616.3; = p.R609* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs376118883; called by muse, mutect2, varscan2
- ASB12 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748815216, COSV62857329; called by muse, mutect2, varscan2
- ASMTL | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs774916001, COSV67244692; called by muse, mutect2, varscan2
- B4GALNT3 | c.2381-1G>C p.X794_splice | Splice Site (SNP) | VAF 27/81 reads (33%) | catalogued as COSV56755902; called by muse, mutect2, varscan2
- BIN2 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.779); catalogued as rs1247356518, COSV53331112; called by muse, mutect2
- CA9 | c.1286T>C p.V429A | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV61407046; called by muse, mutect2
- CD5L | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 35/157 reads (22%) | catalogued as rs1164447478, COSV63822678; called by muse, mutect2, varscan2
- CDH23 | c.5167C>T p.R1723C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs978942792, COSV56478726; called by muse, mutect2, varscan2
- CIITA | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs770284013, COSV60860109; called by muse, mutect2, varscan2
- CNTF | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60157826; called by muse, mutect2, varscan2
- COL4A1 | c.2342G>T p.R781I | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV65429174; called by muse, mutect2, varscan2
- CREBBP | c.4412T>A p.I1471N | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52134080; called by muse, mutect2, varscan2
- CRISPLD2 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV52281679; called by muse, mutect2, varscan2
- CSMD3 | c.1516T>G p.S506A (on ENST00000297405 / NM_001363185.1; = p.S402A on NM_052900.3) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV52258366; called by muse, mutect2, varscan2
- CSTF2T | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs771847513, COSV100484213, COSV58657156; called by muse, mutect2, varscan2
- CTNNA2 | c.1942G>T p.D648Y | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV58167191; called by muse, mutect2
- CUX1 | c.990G>T p.Q330H (on ENST00000292535 / NM_181552.4; = p.Q341H on NM_001913.5) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52908656; called by muse, mutect2, varscan2
- DEPDC5 | c.3614A>G p.H1205R (on ENST00000400246; = p.H1274R on NM_014662.5) | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.832); catalogued as COSV56704889; called by muse, mutect2, varscan2
- DGKK | c.3809A>C p.Q1270P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV65708788; called by muse, mutect2
- DHX16 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs747886418, COSV64581439; called by muse, mutect2, varscan2
- DMD | c.5419C>A p.L1807M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs1368648645, COSV63777008; called by muse, mutect2, varscan2
- DMD | c.1923A>C p.E641D | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.132); catalogued as COSV55874842; called by muse, mutect2, varscan2
- DOC2A | c.729G>T p.E243D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV58752186; called by muse, mutect2, varscan2
- DOCK2 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56975150; called by muse, mutect2, varscan2
- DYNC1H1 | c.6850C>A p.L2284M | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64139919, COSV64140392; called by muse, mutect2
- ENKUR | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751596707, COSV58633319; called by muse, mutect2, varscan2
- EPHA3 | c.1687T>G p.L563V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV60717563; called by muse, mutect2
- FAT4 | c.8141T>A p.M2714K | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58699174; called by muse, mutect2, varscan2
- FBN1 | c.7727G>A p.R2576H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs369888822, COSV57318792; called by muse, mutect2, varscan2
- FBN1 | c.5760C>A p.F1920L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57325144; called by muse, mutect2
- FILIP1 | c.3326_3328del p.L1109del | In Frame Del (DEL) | VAF 22/164 reads (13%) | catalogued as rs776863722; called by mutect2, pindel, varscan2
- FRMPD2 | c.2299G>T p.A767S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV59721323; called by muse, mutect2, varscan2
- FRS3 | c.1222G>T p.G408W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.908); catalogued as COSV52485764; called by muse, mutect2, varscan2
- FSIP2 | c.19885C>A p.L6629I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771710858; called by muse, mutect2, varscan2
- GABPB2 | c.1318A>G p.R440G | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64461229; called by muse, mutect2, varscan2
- GABRA3 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64796513, COSV64802745; called by muse, mutect2, varscan2
- GABRG1 | c.412A>G p.N138D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.977); catalogued as COSV54958573; called by muse, mutect2, varscan2
- GRM5 | c.2552A>C p.K851T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV59617648; called by muse, mutect2, varscan2
- HSPA12A | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65023286; called by muse, mutect2
- HSPD1 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as COSV52099457; called by muse, mutect2, varscan2
- IKZF4 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1245130001, COSV56270208; called by muse, mutect2, varscan2
- KCNT2 | c.3296+2T>C p.X1099_splice | Splice Site (SNP) | VAF 14/147 reads (10%) | catalogued as COSV54096289; called by muse, varscan2
- KIAA1109 | c.13642G>T p.V4548F | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52684989; called by muse, mutect2
- KIAA1614 | c.2322A>T p.E774D | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV62551415; called by muse, mutect2, varscan2
- KIF22 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV50716923; called by muse, mutect2
- KRT24 | c.1569A>C p.K523N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV52881193; called by muse, mutect2, varscan2
- LPAR4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV70912654; called by muse, mutect2, varscan2
- LRRC6 | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51545218; called by muse, mutect2
- MAGEA6 | c.344A>T p.K115M | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV61449252; called by muse, mutect2
- MAGEC3 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV74217374; called by muse, mutect2, varscan2
- MED12 | c.6454G>A p.A2152T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV61349294; called by muse, mutect2, varscan2
- MEIS2 | c.223C>T p.R75W (on ENST00000561208 / NM_170675.5; = p.R62W on NM_002399.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54941291; called by muse, mutect2, varscan2
- NLRP11 | c.271+1G>A p.X91_splice | Splice Site (SNP) | VAF 18/172 reads (10%) | catalogued as rs372781070; called by muse, mutect2, varscan2
- OIT3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs540046250, COSV61826828; called by muse, mutect2, varscan2
- PCDH11X | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53480280; called by muse, mutect2, varscan2
- PCLO | c.10774C>T p.R3592C | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765033421, COSV61652856; called by muse, mutect2, varscan2
- PKD1 | c.3907G>A p.A1303T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs761686050, COSV51916510; called by muse, mutect2, varscan2
- PPEF2 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54424834; called by muse, mutect2, varscan2
- PPP2R5A | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54788932; called by muse, mutect2, varscan2
- PTCH1 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs202136156, COSV59481818; called by muse, mutect2, varscan2
- RAB11FIP4 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201037647, COSV57931349; called by muse, mutect2
- RALGAPB | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV53441602; called by muse, mutect2
- RNF122 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV56359736; called by muse, mutect2, varscan2
- RNF31 | c.2349G>C p.K783N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60727783; called by muse, mutect2, varscan2
- RPH3A | c.1205A>G p.Y402C (on ENST00000389385 / NM_001143854.2; = p.Y398C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66992194; called by muse, mutect2, varscan2
- RUFY3 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs373555907; called by muse, mutect2, varscan2
- SERGEF | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV56385947; called by muse, mutect2, varscan2
- SH3PXD2A | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63512046; called by muse, mutect2, varscan2
- SI | c.4788A>T p.Q1596H | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52291071; called by muse, mutect2
- SLC27A6 | c.664_665insG p.I222Sfs*16 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | catalogued as COSV99323156; called by mutect2, pindel, varscan2
- SLC2A10 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.265); catalogued as COSV63715569; called by muse, mutect2
- SLC66A2 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV60842405, COSV60844210; called by muse, mutect2, varscan2
- SLCO6A1 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as rs539137924, COSV65805537; called by muse, mutect2, varscan2
- SLIT2 | c.4103A>T p.D1368V | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56585280; called by muse, mutect2, varscan2
- SLITRK6 | c.1517T>G p.L506R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68391061; called by muse, mutect2, varscan2
- SPARC | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs142207246; called by muse, mutect2, varscan2
- SPEG | c.9076C>A p.H3026N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56675789; called by muse, mutect2, varscan2
- SPIB | c.247T>A p.Y83N | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54532025; called by muse, varscan2
- SPOPL | c.1096T>A p.L366I | Missense Mutation (SNP) | VAF 33/421 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV54515054; called by muse, mutect2
- SVEP1 | c.1429A>G p.K477E | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs756282528, COSV57042807; called by muse, mutect2, varscan2
- TDRD7 | c.3089A>G p.N1030S | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV62430496; called by muse, mutect2
- TET1 | c.5231G>C p.R1744T | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV65387371; called by muse, varscan2
- TLL1 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV50307475, COSV50324390; called by muse, mutect2, varscan2
- TLR4 | c.1318T>G p.F440V (on ENST00000355622 / NM_138554.5; = p.F400V on NM_003266.4) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV62923866; called by muse, mutect2, varscan2
- TPD52L1 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.422); catalogued as COSV59192945; called by muse, varscan2
- TPTE2 | c.476T>G p.I159S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV55018014, COSV55025454; called by muse, mutect2
- TRIM33 | c.1466A>T p.N489I | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV61824561; called by muse, mutect2, varscan2
- TRPA1 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.844); catalogued as COSV51569118; called by muse, mutect2, varscan2
- TRPM1 | c.3487G>A p.V1163M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV56638810; called by muse, mutect2, varscan2
- TRPS1 | c.2939T>G p.L980* (on ENST00000220888 / NM_001330599.2; = p.L993* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/377 reads (9%) | catalogued as COSV55253714; called by muse, mutect2
- TTN | c.22903G>A p.E7635K (on ENST00000591111; = p.E6708K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/142 reads (11%) | PolyPhen possibly damaging (0.469); catalogued as rs752227139, COSV60103930, COSV60185375; called by muse, mutect2, varscan2
- TXLNA | c.1187A>T p.E396V | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65314936; called by muse, mutect2
- UBR5 | c.5255T>G p.L1752* | Nonsense Mutation (SNP) | VAF 56/145 reads (39%) | catalogued as COSV55294835; called by muse, mutect2, varscan2
- UGT2B28 | c.323_324insG p.Y108* | Nonsense Mutation (INS) | VAF 15/70 reads (21%) | catalogued as COSV100158926; called by mutect2, pindel, varscan2
- UTP14A | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV64087492; called by muse, mutect2
- VPS50 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52496233; called by muse, mutect2, varscan2
- XRN1 | c.4274T>C p.M1425T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.006); catalogued as COSV53815568; called by muse, mutect2, varscan2
- ZGPAT | c.40C>G p.R14G | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs769739125, COSV60832913; called by muse, mutect2
- ZNF835 | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as COSV73379623; called by muse, mutect2, varscan2
- DNAH3 | c.8774A>T p.K2925I | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.8773A>C p.K2925Q | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HJURP | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- NEK8 | c.1958dup p.L654Tfs*9 | Frame Shift Ins (INS) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- OBSCN | c.10790G>T p.G3597V | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- PARD3B | c.2267_2268dup p.V757Rfs*40 (on ENST00000406610 / NM_001302769.2; = p.V695Rfs*40 on NM_152526.6) | Frame Shift Ins (INS) | VAF 30/185 reads (16%) | called by mutect2, pindel, varscan2
- TRMT11 | c.708del p.F236Lfs*10 | Frame Shift Del (DEL) | VAF 38/356 reads (11%) | called by mutect2, pindel, varscan2
- TTN | c.40024_40025del p.K13342Gfs*5 (on ENST00000591111; = p.K5918Gfs*5 on NM_003319.4) | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- UGT2A2 | c.62T>A p.L21* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- ACAN | c.657C>A p.G219= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100719429, COSV61365606; called by muse, mutect2, varscan2
- AMBRA1 | c.3297G>A p.V1099= (on ENST00000458649 / NM_001367468.1; = p.V1009= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV54059532; called by muse, mutect2, varscan2
- ANK2 | c.4254C>T p.R1418= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs778974823, COSV52177177; ClinVar: likely benign; called by muse, mutect2, varscan2
- AR | c.657T>G p.T219= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV101017155, COSV65952694; called by muse, mutect2, varscan2
- AR | c.1254T>A p.G418= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV65961096; called by muse, mutect2
- ARFRP1 | c.540C>T p.I180= | Silent (SNP) | VAF 17/162 reads (10%) | catalogued as rs201441698, COSV53926495; called by muse, mutect2, varscan2
- ARHGAP31 | c.3222C>T p.S1074= | Silent (SNP) | VAF 67/292 reads (23%) | catalogued as rs763588526, COSV51793481; called by muse, mutect2, varscan2
- C5 | c.1074T>G p.A358= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as COSV56330430; called by muse, mutect2, varscan2
- CHRNB2 | c.1116C>T p.G372= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs1402931071, COSV63809021; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL11A2 | c.2607C>A p.P869= (on ENST00000341947 / NM_080680.3; = p.P762= on NM_080679.2) | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- DNAH2 | c.4479T>G p.A1493= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV66723255; called by muse, mutect2, varscan2
- DSG3 | c.1104C>T p.T368= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV57128287; called by muse, mutect2
- ERBB4 | c.2910G>A p.L970= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1439411487, COSV61508205; called by muse, mutect2, varscan2
- FAM71A | c.780C>T p.P260= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as COSV54236537; called by muse, mutect2, varscan2
- FCRL1 | c.831G>A p.E277= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV63826434, COSV63827274; called by muse, mutect2, varscan2
- FLG | c.4704C>T p.A1568= | Silent (SNP) | VAF 152/498 reads (31%) | catalogued as rs766533034, COSV100910376, COSV64238428; called by muse, mutect2, varscan2
- FNTB | c.766C>T p.L256= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs781068835, COSV55763116; called by muse, mutect2, varscan2
- GABRB1 | c.111G>A p.V37= | Silent (SNP) | VAF 51/214 reads (24%) | catalogued as rs1398349763, COSV54992830; called by muse, mutect2, varscan2
- GUCY2F | c.2628A>G p.E876= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV54306053; called by muse, mutect2, varscan2
- HAS2 | c.1476G>C p.V492= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as COSV58265990; called by muse, mutect2, varscan2
- ITGA3 | c.2490G>A p.L830= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV50325907; called by muse, mutect2, varscan2
- JAK1 | c.2931C>G p.L977= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV61094504; called by muse, mutect2, varscan2
- JAKMIP1 | c.264C>T p.R88= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV51539621, COSV99289917; called by muse, mutect2, varscan2
- KANK2 | c.1515C>T p.N505= (on ENST00000586659 / NM_001379562.1; = p.N513= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs769996752, COSV62006335; called by mutect2, varscan2
- KCNQ5 | c.1629A>T p.P543= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV59673481; called by muse, mutect2, varscan2
- KRTAP10-5 | c.33C>T p.S11= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs139901000, COSV59972160; called by muse, mutect2, varscan2
- MUC2 | c.3324C>T p.C1108= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs768500439; called by muse, mutect2
- OBSCN | c.14721C>T p.T4907= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs191407888, COSV52804174; called by muse, mutect2, varscan2
- OLR1 | c.777T>C p.A259= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV58872276; called by muse, mutect2, varscan2
- OR2AE1 | c.732C>A p.L244= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV60390705; called by muse, mutect2, varscan2
- PLCE1 | c.1659C>T p.V553= | Silent (SNP) | VAF 21/223 reads (9%) | catalogued as rs943937024, COSV53336807; called by muse, mutect2
- PTPRT | c.3909C>T p.F1303= | Silent (SNP) | VAF 26/191 reads (14%) | catalogued as rs34623060; called by muse, mutect2, varscan2
- SLC4A10 | c.3084G>A p.T1028= (on ENST00000446997 / NM_001354461.2; = p.T998= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs755017808, COSV55790909; called by muse, mutect2, varscan2
- SOGA3 | c.2307G>A p.P769= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV64104949; called by muse, mutect2, varscan2
- SOX17 | c.645C>T p.D215= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV52025479; called by muse, mutect2
- TKTL2 | c.1428C>A p.T476= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as COSV54920390; called by muse, mutect2, varscan2
- TRBV4-1 | c.318C>T p.A106= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as rs764914073; called by muse, varscan2
- TRIM27 | c.1290G>A p.R430= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as rs1346443036, COSV65873854; called by muse, mutect2, varscan2
- ZNF484 | c.1608G>A p.K536= | Silent (SNP) | VAF 20/193 reads (10%) | catalogued as rs1445416297, COSV60258926; called by muse, mutect2, varscan2
- ZNF648 | c.840G>A p.A280= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1345959176, COSV60572100; called by muse, mutect2, varscan2
- CUTA | c.-86G>C | 5'UTR (SNP) | VAF 20/89 reads (22%) | catalogued as COSV99538692; called by muse, mutect2, varscan2
- MIR506 | n.63A>G | RNA (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- SUPT3H | c.-104G>A | 5'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
